Somatic mutation profile of tumor specimen TCGA-FD-A3SP-01A (aliquot TCGA-FD-A3SP-01A-31D-A22Z-08) from TCGA case TCGA-FD-A3SP, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 60.2 years (22,005 days).
Specimen TCGA-FD-A3SP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1509f19-0097-4447-b758-44be70679faa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SP-10A (Blood Derived Normal), aliquot TCGA-FD-A3SP-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b77b9cb-935a-4098-84cd-00e146571448

The open-access MAF lists 134 somatic variants for this specimen: 95 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 35, Nonsense Mutation 9, Frame Shift Del 4, 5'Flank 2, Splice Region 2, Intron 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL2 | c.149G>C p.R50T | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1567626023, COSV58026196, COSV58030422; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- ACSM5 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1383760183, COSV59371329; called by muse, mutect2, varscan2
- AK9 | c.3133G>C p.D1045H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); catalogued as COSV58142278; called by muse, mutect2
- AKAP9 | c.902T>C p.L301S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62345939; called by muse, mutect2, varscan2
- ARFGEF2 | c.4629G>T p.Q1543H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV64212245; called by muse, mutect2
- ASB4 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141186023; called by muse, mutect2, varscan2
- ATP7A | c.2628G>C p.G876= | Splice Region (SNP) | VAF 12/61 reads (20%) | catalogued as COSV58446215; called by muse, mutect2, varscan2
- AXL | c.1244G>C p.G415A | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV56568169; called by muse, mutect2, varscan2
- CASP9 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61601456; called by muse, mutect2, varscan2
- CELSR2 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54771582; called by muse, mutect2
- CNTROB | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV58050227; called by muse, mutect2
- COG4 | c.1992G>C p.M664I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV55370700; called by muse, mutect2, varscan2
- CPNE6 | c.1299G>A p.T433= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as rs371553770; called by muse, mutect2, varscan2
- CRABP1 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55115777; called by muse, mutect2, varscan2
- CX3CL1 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50055854; called by muse, mutect2, varscan2
- CYP20A1 | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61909469; called by muse, mutect2, varscan2
- DENND6A | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV60770247; called by muse, mutect2, varscan2
- DIAPH2 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100230484, COSV61260565; called by muse, mutect2, varscan2
- DSCAML1 | c.5212G>A p.D1738N (on ENST00000321322; = p.D1678N on NM_020693.4) | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58390383; called by muse, mutect2
- DYNC2LI1 | c.633T>G p.H211Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53183473; called by muse, mutect2, varscan2
- EEA1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV59285717; called by muse, mutect2, varscan2
- EHBP1L1 | c.1687G>T p.E563* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100499796, COSV58574859; called by muse, mutect2
- FLG | c.5111C>G p.S1704C | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100910390, COSV64241733; called by muse, mutect2
- HBS1L | c.1953A>G p.I651M | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV63201251; called by muse, mutect2, varscan2
- KDM5C | c.2266C>A p.L756I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781903902, COSV64766153; called by muse, mutect2
- KMT2D | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99979762; called by muse, varscan2
- KMT2D | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV56439011, COSV56484054; called by mutect2, varscan2
- KRT14 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV51421312; called by muse, mutect2
- LIG4 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV63597037; called by muse, mutect2, varscan2
- LMTK2 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1384475759, COSV51995071; called by muse, mutect2
- MAGI2 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV62657574; called by muse, mutect2, varscan2
- MAMDC4 | c.3534G>C p.Q1178H (on ENST00000445819; = p.Q1099H on NM_206920.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV56375785; called by muse, mutect2, varscan2
- MAP1A | c.3621G>C p.E1207D | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100289273, COSV55805892, COSV55808673; called by muse, mutect2, varscan2
- MAP4 | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53137586; called by muse, mutect2, varscan2
- MRPS26 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV55661679; called by muse, mutect2
- MYO1D | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1191926035, COSV59012854; called by muse, mutect2, varscan2
- NCOA2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71763963; called by muse, mutect2, varscan2
- NCOR1 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as COSV51974323; called by muse, mutect2, varscan2
- NSD1 | c.4168G>C p.E1390Q | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV61776142; called by muse, varscan2
- NYAP2 | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752903462, COSV56004733; called by muse, mutect2, varscan2
- OMP | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV53687770; called by muse, mutect2, varscan2
- OR10R2 | c.260C>G p.S87* | Nonsense Mutation (SNP) | VAF 28/209 reads (13%) | catalogued as COSV63768378; called by muse, mutect2, varscan2
- OR2L3 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV63455147; called by muse, mutect2, varscan2
- OR2T10 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV57896863; called by muse, mutect2, varscan2
- OXSM | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746852820, COSV55001216; called by muse, mutect2, varscan2
- PAN3 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1468127178, COSV66708603; called by muse, mutect2, varscan2
- PAX3 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1246737713, COSV60587612; called by muse, mutect2
- PCDHA8 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV65336233, COSV65336978; called by muse, mutect2, varscan2
- PGM5 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs200812025; called by muse, mutect2, varscan2
- PIP5K1C | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs752082603, COSV58952289; called by muse, mutect2, varscan2
- PPP1R1B | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV54201588, COSV54202149; called by muse, mutect2, varscan2
- PPP6R1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV69799719; called by muse, mutect2
- PSD4 | c.221A>G p.H74R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.094); catalogued as COSV55526697; called by muse, mutect2, varscan2
- PTPRF | c.5369G>A p.G1790E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63444892; called by muse, mutect2, varscan2
- PTPRK | c.3568G>A p.E1190K (on ENST00000368215 / NM_001291984.2; = p.E1191K on NM_002844.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV63897561; called by muse, mutect2, varscan2
- PWWP2B | c.929C>A p.S310* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100535706, COSV59452658; called by muse, mutect2, varscan2
- RANBP2 | c.9485A>G p.N3162S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs141352150; called by muse, mutect2, varscan2
- RARB | c.384G>C p.K128N (on ENST00000383772 / NM_001290216.2; = p.K121N on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV58067344; called by muse, mutect2
- RFX5 | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.967); catalogued as COSV51839133; called by muse, mutect2, varscan2
- RNF182 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.587); catalogued as COSV70369194; called by muse, mutect2
- SALL1 | c.2023C>G p.P675A | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51753329, COSV51757244; called by muse, mutect2, varscan2
- SAMHD1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1482152853, COSV53429009; called by muse, mutect2
- SECISBP2L | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as COSV55934368; called by muse, mutect2, varscan2
- SLC27A6 | c.1691T>A p.M564K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52482911; called by muse, mutect2
- SLC6A20 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs376448611, COSV62071271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK6 | c.2069A>G p.Y690C | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV68390164; called by muse, mutect2, varscan2
- STRAP | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50308527; called by muse, mutect2, varscan2
- SUSD3 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV64937226; called by muse, mutect2, varscan2
- SVIL | c.1817A>T p.N606I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV63443335; called by muse, mutect2, varscan2
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | catalogued as rs750901207; called by mutect2, pindel
- THOC5 | c.1189C>G p.P397A | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV63798667, COSV63801095; called by muse, mutect2, varscan2
- TPP2 | c.3427G>A p.G1143R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs756043080, COSV101060356, COSV65752570; called by muse, mutect2, varscan2
- TRHDE | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV53843951; called by muse, mutect2
- TRIL | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV59867074, COSV59867239; called by muse, mutect2, varscan2
- TRPC4 | c.2136C>A p.N712K (on ENST00000379705 / NM_016179.4; = p.N717K on NM_003306.3) | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.299); catalogued as COSV58999761; called by muse, mutect2
- TRPM7 | c.5227A>T p.T1743S | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.05); catalogued as COSV57916256; called by muse, mutect2
- UBE2J1 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV70561390; called by muse, mutect2
- ULK2 | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.795); catalogued as COSV64445702; called by muse, mutect2, varscan2
- VPS13D | c.11713G>A p.E3905K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as rs1483679981, COSV50626792; called by muse, mutect2, varscan2
- WBP2NL | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV60919438; called by muse, mutect2
- XIRP2 | c.3397G>A p.D1133N (on ENST00000628543; = p.D1308N on NM_152381.6) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs770267729, COSV54696966; called by muse, mutect2, varscan2
- ARID1A | c.4608_4612del p.D1536Efs*34 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- CYP4Z1 | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- DNAH3 | c.11533dup p.Q3845Pfs*12 | Frame Shift Ins (INS) | VAF 30/159 reads (19%) | called by mutect2, pindel, varscan2
- ELOVL5 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- GPR89A | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- KDM6B | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MAMDC4 | c.3052G>A p.E1018K (on ENST00000445819; = p.E939K on NM_206920.3) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2
- NOX4 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- PRICKLE1 | c.2193C>A p.Y731* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- RARB | c.166_167del p.P56Vfs*6 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel
- RCOR3 | c.21C>A p.Y7* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- ZZZ3 | c.816del p.V273Cfs*10 | Frame Shift Del (DEL) | VAF 33/270 reads (12%) | called by mutect2, pindel, varscan2
- ADARB2 | c.1002C>T p.A334= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs774427511, COSV67222888; called by muse, mutect2, varscan2
- ANGPTL4 | c.198G>C p.L66= | Silent (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- ASXL1 | c.1671C>G p.T557= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as rs372630902, COSV60107798, COSV60127042; called by muse, mutect2, varscan2
- ATRNL1 | c.3624C>T p.V1208= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs564438918, COSV58087750; called by muse, mutect2, varscan2
- BMP4 | c.429C>T p.N143= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV55415923; called by muse, mutect2, varscan2
- CELSR3 | c.4047C>T p.S1349= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1279148243, COSV50858662; called by mutect2, varscan2
- CKAP5 | c.3453G>A p.K1151= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV56367412, COSV56367668; called by muse, mutect2, varscan2
- COL6A3 | c.972C>T p.L324= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs761334907, COSV55089055; called by muse, mutect2, varscan2
- DAB2 | c.1797T>C p.F599= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as COSV57914322; called by muse, mutect2
- DGCR8 | c.267G>A p.P89= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV61226640; called by muse, mutect2, varscan2
- DGKG | c.423G>A p.A141= | Silent (SNP) | VAF 53/246 reads (22%) | catalogued as rs754146827, COSV53965030; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1368G>A p.S456= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs772850807, COSV50051538; called by muse, mutect2, varscan2
- EMP2 | c.300C>T p.I100= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV63995922; called by muse, mutect2, varscan2
- FCRL5 | c.669G>A p.P223= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs761744976, COSV62514453; called by muse, mutect2, varscan2
- GBP1 | c.672C>G p.L224= | Silent (SNP) | VAF 25/473 reads (5%) | catalogued as COSV65083417; called by muse, mutect2
- GPX1 | c.576C>A p.I192= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- INPP4B | c.1980G>T p.G660= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV53724468; called by muse, mutect2
- ITGA7 | c.2931C>T p.S977= (on ENST00000555728; = p.S933= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV57695177; called by muse, mutect2, varscan2
- LDHC | c.612G>C p.V204= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs780800786, COSV55004265; called by muse, mutect2, varscan2
- LRFN1 | c.750C>T p.G250= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1185004699, COSV50436389; called by muse, mutect2
- MUC15 | c.303A>G p.K101= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV55554333; called by muse, mutect2, varscan2
- OR2T2 | c.552C>A p.A184= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as COSV61617751; called by muse, mutect2, varscan2
- PCDHA8 | c.2040G>A p.S680= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as rs368338560; called by muse, mutect2
- PLEKHG7 | c.372C>T p.P124= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV67337836; called by muse, mutect2
- QARS1 | c.1557C>T p.L519= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV60273681, COSV60274933; called by muse, mutect2, varscan2
- RPS6 | c.747A>G p.K249= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV59547895; called by muse, mutect2
- SEZ6 | c.426G>A p.P142= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs749642733, COSV57979828; called by muse, varscan2
- SMC2 | c.3408A>G p.T1136= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1225566620, COSV53958051; called by muse, mutect2, varscan2
- SMYD5 | c.129G>A p.R43= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV50264814; called by muse, mutect2, varscan2
- SNAPC4 | c.2856C>T p.L952= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV53733130; called by muse, mutect2, varscan2
- STRN4 | c.630C>T p.N210= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs146403716; called by muse, mutect2, varscan2
- TP53 | c.960G>A p.K320= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV52868386, COSV52964855, COSV53245158; called by muse, mutect2, varscan2
- VIL1 | c.408C>T p.V136= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as COSV50287894; called by muse, mutect2, varscan2
- ZNF311 | c.264C>T p.L88= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV65853098; called by muse, mutect2
- ZNF615 | c.1005G>A p.Q335= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV65033206; called by muse, mutect2, varscan2
- ELOB | c.*511G>T | 3'UTR (SNP) | VAF 30/95 reads (32%) | catalogued as COSV51940660; called by muse, mutect2, varscan2
- LRRFIP1 | c.154-1738A>G | Intron (SNP) | VAF 26/132 reads (20%) | catalogued as COSV55251871; called by muse, mutect2, varscan2
- MFRP | chr11:119345615 G>C | 5'Flank (SNP) | VAF 7/36 reads (19%) | catalogued as COSV64128351; called by muse, mutect2, varscan2
- MFRP | chr11:119345833 G>C | 5'Flank (SNP) | VAF 11/75 reads (15%) | catalogued as CM123466, COSV64128354; called by muse, mutect2, varscan2
